Gene-level copy-number profile of tumor specimen TCGA-Q1-A6DT-01A from TCGA case TCGA-Q1-A6DT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 55.5 years (20,286 days).
Specimen TCGA-Q1-A6DT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.ea7c33ff-961d-49c7-a6cc-4d9bdeaa251a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q1-A6DT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4168b62-26da-4e03-818d-713d6e8d8801

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,019; copy number 2: 20,963; copy number 3: 21,273; copy number 4: 9,524; copy number 5: 2,582; copy number 6: 2,513; copy number 7: 572; copy number 8: 123; copy number 9: 119; copy number 11: 9; copy number 12: 83; copy number 14: 3; copy number 16: 12; copy number 20: 2; copy number 21: 3; copy number 54: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q1-A6DT-01A-11D-A32H-01): tumor purity 0.57, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,586 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,715,609–62,178,675, 34 genes, copy number 5–54 (within-gene range 4–54): AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P.
- chr1:63,139,250–63,660,245, 25 genes, copy number 6: AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P.
- chr1:63,788,721–63,789,304, 1 gene, copy number 6: AL161742.1.
- chr1:119,368,779–121,580,524, 65 genes, copy number 7–11 (broad region; genes not listed).
- chr1:154,548,577–157,417,259, 151 genes, copy number 7 (broad region; genes not listed).
- chr1:157,925,065–158,149,810, 5 genes, copy number 6: AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704.
- chr1:159,346,166–161,964,070, 133 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr1:164,343,005–165,698,863, 26 genes, copy number 6–11 (within-gene range 3–11): NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P, LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2.
- chr1:167,430,640–169,132,722, 46 genes, copy number 8–21: CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1.
- chr2:188,598,791–192,044,525, 60 genes, copy number 5 (within-gene range 3–5): AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1.
- chr3:26,346,681–36,993,131, 123 genes, copy number 5–6 (broad region; genes not listed).
- chr3:37,693,655–38,542,161, 26 genes, copy number 5 (within-gene range 3–5): ITGA9-AS1, RPL21P135, NDUFAF4P3, CTDSPL, MIR26A1, VILL, PLCD1, Y_RNA, DLEC1, PPP2R2DP1, ACAA1, Y_RNA, MYD88, OXSR1, SLC22A13, AP006193.1, SLC22A14, RNU6-235P, DLEC1P1, XYLB, ACVR2B-AS1, ACVR2B, EXOG, Y_RNA, DDTP1, RPL18AP7.
- chr3:69,168,782–69,968,336, 7 genes, copy number 12–20 (within-gene range 2–20): FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P.
- chr3:70,954,708–71,827,471, 13 genes, copy number 7 (within-gene range 5–11): FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P.
- chr3:81,208,193–81,764,756, 9 genes, copy number 5–8: AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2.
- chr3:138,889,255–198,222,513, 1,038 genes, copy number 6 (broad region; genes not listed).
- chr4:67,417,305–74,794,523, 169 genes, copy number 5 (broad region; genes not listed).
- chr4:76,708,853–78,939,438, 40 genes, copy number 5: SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P.
- chr4:81,426,393–82,276,600, 8 genes, copy number 6 (within-gene range 4–6): RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1.
- chr5:58,198–45,895,970, 710 genes, copy number 5–8 (broad region; genes not listed).
- chr6:106,695,535–111,231,194, 99 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr7:70,972–57,655,392, 1,065 genes, copy number 6 (broad region; genes not listed).
- chr7:97,005,553–97,201,483, 6 genes, copy number 5: DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1.
- chr7:101,562,779–101,629,296, 2 genes, copy number 6: LINC01007, MYL10.
- chr8:35,672,195–37,758,422, 34 genes, copy number 6: AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2.
- chr10:62,183,035–63,658,521, 25 genes, copy number 5: RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr11:61,792,980–61,867,354, 1 gene, copy number 5 (within-gene range 3–5): FADS2.
- chr11:61,873,519–72,139,892, 527 genes, copy number 5 (broad region; genes not listed).
- chr12:43,155,315–43,806,328, 10 genes, copy number 5: LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:79,773,563–79,935,460, 1 gene, copy number 6 (within-gene range 3–6): PPP1R12A.
- chr12:79,878,305–80,380,879, 7 genes, copy number 6 (within-gene range 2–6): RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1.
- chr12:123,152,320–123,244,014, 1 gene, copy number 5 (within-gene range 2–5): MPHOSPH9.
- chr12:123,233,436–123,935,720, 31 genes, copy number 5: C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2, DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2, TCTN2, AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4, DNAH10.
- chr18:30,290,161–31,162,856, 11 genes, copy number 6: AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1.
- chr19:37,884,823–38,426,305, 24 genes, copy number 7–21: WDR87, SIPA1L3, AC008395.1, AC011465.1, AC011479.3, AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4.
- chr19:52,904,417–54,602,381, 173 genes, copy number 5–7 (broad region; genes not listed).
- chr19:55,027,593–55,836,800, 71 genes, copy number 12 (within-gene range 4–12) (broad region; genes not listed).
- chr19:57,111,120–58,605,223, 132 genes, copy number 5–8 (broad region; genes not listed).
- chr20:87,250–31,834,689, 605 genes, copy number 5 (broad region; genes not listed).
- chr20:49,903,391–53,495,330, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
